Somatic mutation profile of tumor specimen MMRF_2768_1_BM_CD138pos (aliquot MMRF_2768_1_BM_CD138pos_T1_KHS5U_L15719) from MMRF case MMRF_2768, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.1 years (24,127 days).
Specimen MMRF_2768_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d70a3876-65d3-4c71-a193-8c181b569ed9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2768_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2768_1_PB_WBC_C2_KHS5U_L15763; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5aae6033-b4b9-439f-9f8b-d40cc7bc3fd8

The open-access MAF lists 83 somatic variants for this specimen: 37 protein-altering or splice-affecting, 8 silent, 38 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, 3'UTR 19, Intron 14, Silent 8, 5'UTR 3, Nonsense Mutation 2, 3'Flank 1, Splice Site 1, Frame Shift Del 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANK1 | c.2971G>A p.V991M | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs758454168, COSV55875928; called by muse, mutect2, varscan2
- B4GALNT4 | c.1448G>A p.R483Q | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs558666429; called by muse, mutect2, varscan2
- CACNA1B | c.6071C>T p.T2024M | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.475); catalogued as rs1317101682, COSV53129778; called by muse, mutect2
- CARD8 | c.1433A>G p.N478S (on ENST00000651546 / NM_001184900.3; = p.N428S on NM_014959.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.012); catalogued as rs1413888232; called by muse, mutect2
- CCDC6 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.186); catalogued as rs370071074; called by muse, mutect2, varscan2
- DDX52 | c.1621T>C p.Y541H | Missense Mutation (SNP) | VAF 4/68 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs1362716439; called by muse, mutect2
- DST | c.22028G>A p.R7343Q (on ENST00000361203 / NM_001374722.1; = p.R5053Q on NM_015548.5) | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs372639720, COSV55013488; called by muse, mutect2, varscan2
- FAM83H | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as COSV66354598; called by muse, mutect2, varscan2
- FILIP1 | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs369386052, COSV52741820; called by muse, mutect2, varscan2
- GUCY2C | c.3014A>G p.D1005G | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV53790477; called by muse, mutect2, varscan2
- HYI | c.511G>A p.V171M (on ENST00000372434 / NM_001330526.2; = p.V146M on NM_031207.6) | Missense Mutation (SNP) | VAF 126/319 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as rs768169677; called by muse, mutect2, varscan2
- IGLV3-1 | c.80C>A p.P27H | Missense Mutation (SNP) | VAF 59/166 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.141); catalogued as rs763621186; called by muse, varscan2
- IGLV3-1 | c.207T>G p.D69E | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs376313046; called by muse, mutect2, varscan2
- KIAA1671 | c.2503G>A p.V835M | Missense Mutation (SNP) | VAF 66/180 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs373683646; called by muse, mutect2, varscan2
- KMT2D | c.5863del p.S1955Lfs*92 | Frame Shift Del (DEL) | VAF 16/65 reads (25%) | catalogued as COSV99977553; called by mutect2, pindel*, varscan2
- LTB | c.208+1G>A p.X70_splice | Splice Site (SNP) | VAF 108/276 reads (39%) | catalogued as rs184485821, COSV59864566, COSV59864683; called by muse, mutect2, varscan2
- NEK4 | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 64/345 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs752642184, COSV99237519; called by muse, mutect2, varscan2
- PTPRD | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 12/327 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1029800385, COSV61975466; called by muse, mutect2
- SLC6A5 | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 59/106 reads (56%) | catalogued as COSV100116875; called by muse, mutect2, varscan2
- TTN | c.272G>T p.S91I | Missense Mutation (SNP) | VAF 26/52 reads (50%) | PolyPhen probably damaging (1); catalogued as rs1367815458; called by muse, mutect2, varscan2
- ZMPSTE24 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs555007253, COSV101031864; called by muse, mutect2
- ZSCAN12 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV63011431; called by muse, mutect2, varscan2
- ACTL8 | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 24/168 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- BMP6 | c.1403T>C p.M468T | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- COA7 | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CSMD1 | c.5724C>G p.Y1908* (on ENST00000520002; = p.Y1907* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 48/134 reads (36%) | called by muse, mutect2, varscan2
- EHD3 | c.782C>T p.P261L | Missense Mutation (SNP) | VAF 15/343 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); called by muse, mutect2
- FEM1C | c.5A>T p.D2V | Missense Mutation (SNP) | VAF 63/129 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KDM4B | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 14/318 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- OR9K2 | c.782A>C p.K261T (on ENST00000305377; = p.K239T on NM_001005243.1) | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- P3H1 | c.565A>G p.M189V | Missense Mutation (SNP) | VAF 10/125 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2
- PLIN3 | c.1225_1226insT p.A409Vfs*19 | Frame Shift Ins (INS) | VAF 46/113 reads (41%) | called by mutect2, pindel, varscan2
- S1PR5 | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); called by muse, mutect2, varscan2
- SAMD9 | c.3223A>G p.I1075V | Missense Mutation (SNP) | VAF 27/193 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D15 | c.226T>C p.W76R | Missense Mutation (SNP) | VAF 134/328 reads (41%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRABD2B | c.927G>C p.K309N | Missense Mutation (SNP) | VAF 11/187 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.89); called by muse, mutect2
- TRPM8 | c.2294A>C p.H765P | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- AGRN | c.3861G>A p.R1287= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as rs759115477; called by muse, mutect2, varscan2
- CDX4 | c.330G>A p.S110= | Silent (SNP) | VAF 101/301 reads (34%) | called by muse, mutect2, varscan2
- DAGLA | c.1896C>T p.G632= | Silent (SNP) | VAF 38/134 reads (28%) | catalogued as rs200538416, COSV57197281; called by muse, mutect2, varscan2
- HELZ2 | c.2040G>A p.P680= (on ENST00000467148 / NM_001037335.2; = p.P111= on NM_033405.3) | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as rs370675728, COSV100915381; called by muse, mutect2, varscan2
- HOXC5 | c.291G>T p.G97= | Silent (SNP) | VAF 15/39 reads (38%) | called by muse, mutect2, varscan2
- MYOF | c.4260G>C p.L1420= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs1564634325; called by muse, mutect2, varscan2
- OPLAH | c.60C>T p.D20= | Silent (SNP) | VAF 13/240 reads (5%) | catalogued as rs782783887; called by muse, mutect2
- RFX3 | c.324A>T p.S108= | Silent (SNP) | VAF 39/208 reads (19%) | called by muse, mutect2, varscan2
- ADGRD1 | c.*142del | 3'UTR (DEL) | VAF 13/117 reads (11%) | called by mutect2, pindel, varscan2
- AL359555.4 | n.1406C>A | RNA (SNP) | VAF 32/171 reads (19%) | called by muse, mutect2, varscan2
- ALDH1A2 | c.117+7491_117+7494del | Intron (DEL) | VAF 33/198 reads (17%) | called by mutect2, pindel, varscan2
- ANP32A | c.*464T>C | 3'UTR (SNP) | VAF 38/229 reads (17%) | called by muse, mutect2, varscan2
- CBY2 | c.156+729A>G | Intron (SNP) | VAF 12/106 reads (11%) | catalogued as rs565352947; called by muse, mutect2, varscan2
- CCDC160 | c.-6G>A | 5'UTR (SNP) | VAF 68/274 reads (25%) | called by muse, mutect2, varscan2
- CCDC34 | c.606+317T>C | Intron (SNP) | VAF 7/143 reads (5%) | called by muse, mutect2
- CCNT2 | c.539+139_539+143del | Intron (DEL) | VAF 12/47 reads (26%) | catalogued as rs1169713662; called by pindel, varscan2
- CMKLR1 | c.*41G>A | 3'UTR (SNP) | VAF 5/43 reads (12%) | called by muse, mutect2, varscan2
- COL4A5 | c.*1118T>A | 3'UTR (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- CPLX1 | c.*1190C>T | 3'UTR (SNP) | VAF 13/269 reads (5%) | called by muse, mutect2
- EGR1 | c.-54C>T | 5'UTR (SNP) | VAF 26/68 reads (38%) | catalogued as rs1193688032; called by muse, mutect2, varscan2
- EIF5 | c.*1769C>A | 3'UTR (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
- FAXDC2 | c.846-28C>T | Intron (SNP) | VAF 14/226 reads (6%) | called by muse, mutect2
- GABRG2 | c.*1982G>C | 3'UTR (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- GLUL | c.*1362G>C | 3'UTR (SNP) | VAF 13/51 reads (25%) | called by muse, mutect2, varscan2
- KLHL13 | c.99-2210A>C | Intron (SNP) | VAF 21/59 reads (36%) | called by muse, mutect2, varscan2
- LTB | c.162+36A>C | Intron (SNP) | VAF 28/79 reads (35%) | catalogued as rs539650569; called by muse, mutect2, varscan2
- MFAP3 | c.*1059T>G | 3'UTR (SNP) | VAF 69/181 reads (38%) | called by muse, mutect2, varscan2
- MRPL42 | c.*90+631T>C | Intron (SNP) | VAF 31/57 reads (54%) | catalogued as rs1158877037; called by muse, mutect2, varscan2
- MYLK | c.*4056A>C | 3'UTR (SNP) | VAF 36/101 reads (36%) | called by muse, mutect2, varscan2
- MYO1B | c.3287+142G>A | Intron (SNP) | VAF 7/58 reads (12%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*1743G>A | 3'UTR (SNP) | VAF 20/128 reads (16%) | catalogued as rs985399066, COSV72153098; called by muse, mutect2, varscan2
- PA2G4 | c.88+204G>A | Intron (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- PICK1 | c.*252T>C | 3'UTR (SNP) | VAF 40/124 reads (32%) | called by muse, varscan2
- PTGIS | c.*404G>A | 3'UTR (SNP) | VAF 52/134 reads (39%) | catalogued as rs539460849; called by muse, mutect2, varscan2
- RDH8 | c.*17C>T | 3'UTR (SNP) | VAF 10/90 reads (11%) | catalogued as rs184814224; called by muse, mutect2, varscan2
- SEZ6L2 | c.-18A>T | 5'UTR (SNP) | VAF 65/175 reads (37%) | called by muse, mutect2, varscan2
- SGSM1 | c.*335C>T | 3'UTR (SNP) | VAF 5/80 reads (6%) | catalogued as rs943118795; called by muse, mutect2
- SH2D7 | c.*1309G>A | 3'UTR (SNP) | VAF 33/168 reads (20%) | called by muse, mutect2, varscan2
- SND1 | c.1779+6646C>T | Intron (SNP) | VAF 32/168 reads (19%) | called by muse, mutect2, varscan2
- SP1 | c.8-85A>G | Intron (SNP) | VAF 4/55 reads (7%) | called by muse, mutect2
- SPATA6 | c.*1596G>A | 3'UTR (SNP) | VAF 11/20 reads (55%) | catalogued as rs1489090556; called by muse, mutect2, varscan2
- THBS2 | c.*444C>A | 3'UTR (SNP) | VAF 13/106 reads (12%) | catalogued as rs1241041588; called by muse, mutect2
- TMEM164 | c.*3872T>C | 3'UTR (SNP) | VAF 48/118 reads (41%) | called by muse, mutect2, varscan2
- TMEM80 | c.461-343G>T | Intron (SNP) | VAF 17/85 reads (20%) | called by muse, mutect2, varscan2
- UBFD1 | c.737-114C>T | Intron (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2
- ZBTB38 | chr3:141447056 T>G | 3'Flank (SNP) | VAF 38/124 reads (31%) | called by muse, mutect2, varscan2
